CPTAC case C3N-04683 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/85a832ca-97ce-459f-a8f2-9fa7960ea366

Demographics
Sex at birth: male; Race: white; Year of birth: 1958; Vital status: Dead; Days to death: 439 days (1.2 years); Year of death: 2019; Country of birth: Poland.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Frontal lobe; Age at diagnosis: 60.4 years (22,056 days); Year of diagnosis: 2018; Last known disease status: With tumor; Days to last known disease status: 439 days (1.2 years); Days to last follow up: 393 days (1.1 years).
   Pathology details: Greatest tumor dimension: 5 cm.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (3 entries)
- Days to follow up: 336 days; Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 263 days; Karnofsky performance status: 40; ECOG performance status: 2.
- Days to follow up: 336 days; Disease response: With Tumor; Karnofsky performance status: 40; ECOG performance status: 2.
- Days to follow up: 393 days (1.1 years); Disease response: With Tumor; Karnofsky performance status: 40; ECOG performance status: 3.

Other clinical attributes
- Weight: 75 kg; Height: 173 cm; BMI: 25.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-04683-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -4 days; Initial weight: 288 mg; Time between excision and freezing: 11 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-04683-22: Section location: Frontal Lobe; Percent tumor nuclei: 60; Percent necrosis: 5.
- Sample C3N-04683-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -4 days; Method of sample procurement: Blood Draw.
